Somatic mutation profile of tumor specimen TCGA-13-1411-01A (aliquot TCGA-13-1411-01A-01W-0492-08) from TCGA case TCGA-13-1411, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.8 years (29,874 days).
Specimen TCGA-13-1411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ceeac95-6d3b-48c3-ba25-f8385ff3cd16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1411-10A (Blood Derived Normal), aliquot TCGA-13-1411-10A-01W-0493-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/080dc2a0-bdd6-4ff9-b49c-60fea5231ff1

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 34, Silent 14, Splice Site 6, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 38/72 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL592490.1 | c.2273C>A p.T758N | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69424718; called by muse, mutect2, varscan2
- ALDH8A1 | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99664987; called by muse, mutect2, varscan2
- AMPD3 | c.774G>T p.M258I (on ENST00000396553 / NM_001025389.2; = p.M267I on NM_000480.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101158251; called by muse, mutect2, varscan2
- ASB12 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV62856132; called by muse, mutect2, varscan2
- C12orf40 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763522104, COSV61129619; called by muse, mutect2, varscan2
- C6orf89 | c.826-1G>A p.X276_splice (on ENST00000373685; = p.X283_splice on NM_152734.4) | Splice Site (SNP) | VAF 49/305 reads (16%) | catalogued as COSV62101086; called by muse, mutect2, varscan2
- CCNH | c.951C>G p.D317E | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56924133; called by muse, mutect2, varscan2
- CDC42BPB | c.1641+1G>T p.X547_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100775592; called by muse, mutect2, varscan2
- CLTCL1 | c.2536G>T p.V846L | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54225774; called by muse, mutect2, varscan2
- CSNK2A1 | c.383T>C p.L128S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53933828, COSV53934272; called by muse, mutect2, varscan2
- CYLC1 | c.527A>T p.K176I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV61410163; called by muse, mutect2, varscan2
- CYP1A2 | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV59659094; called by muse, mutect2, varscan2
- CYTIP | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 18/402 reads (4%) | catalogued as COSV99938915; called by muse, mutect2
- DICER1 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749834289, COSV58616061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR45 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV51522825; called by muse, mutect2, varscan2
- GRIN2D | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766471644, COSV54377215; called by muse, mutect2
- IGSF9B | c.3147dup p.L1050Afs*16 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1464678670; called by pindel, varscan2
- KDELR2 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as COSV51725895; called by muse, mutect2, varscan2
- LRRC4C | c.1738C>G p.P580A | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV53418848; called by muse, mutect2, varscan2
- MTMR6 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV67807848; called by muse, mutect2, varscan2
- MTRR | c.1111A>T p.K371* (on ENST00000264668; = p.K344* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/213 reads (10%) | catalogued as rs770198095, COSV99242070; called by muse, mutect2
- NEGR1 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100160092, COSV60832075; called by muse, varscan2
- NIM1K | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58139635; called by muse, mutect2, varscan2
- OIT3 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV61825143, COSV61826539; called by muse, mutect2, varscan2
- PHF20L1 | c.2387+1G>A p.X796_splice | Splice Site (SNP) | VAF 38/309 reads (12%) | catalogued as COSV55189287; called by muse, mutect2, varscan2
- PLPPR5 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54169509; called by muse, mutect2, varscan2
- PRDM9 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 80/814 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs571933768, COSV57003035; called by muse, mutect2
- PRRG3 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64850756; called by muse, mutect2, varscan2
- PUM2 | c.569T>C p.L190S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV57578204; called by muse, mutect2, varscan2
- PXDNL | c.4040G>C p.G1347A | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV62479496; called by muse, mutect2, varscan2
- RAD23B | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV63657760; called by muse, mutect2, varscan2
- RET | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1321002969, COSV100394497; called by muse, mutect2, varscan2
- SIRPB1 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1347891990, COSV53537602; called by muse, mutect2, varscan2
- SLC25A24 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); catalogued as rs1007343871, COSV51446020; called by muse, mutect2, varscan2
- SMARCB1 | c.646G>A p.V216I (on ENST00000263121; = p.V262I on NM_003073.5) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.85); catalogued as rs1341827515, COSV54093872; called by muse, mutect2, varscan2
- SNRPN | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.096); catalogued as COSV57594312; called by muse, mutect2, varscan2
- SNX4 | c.727-2A>T p.X243_splice | Splice Site (SNP) | VAF 5/65 reads (8%) | catalogued as COSV52536194; called by muse, mutect2
- SULF1 | c.223dup p.A75Gfs*48 | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | catalogued as rs747316268; called by mutect2, varscan2
- TBC1D8 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs983037879, COSV65210052; called by muse, mutect2, varscan2
- TBX3 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV99984079; called by muse, varscan2
- TLE4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 98/592 reads (17%) | catalogued as COSV54626871; called by muse, mutect2, varscan2
- USH2A | c.8682-1G>T p.X2894_splice | Splice Site (SNP) | VAF 12/119 reads (10%) | catalogued as COSV56332123; called by muse, mutect2
- ZNF208 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV68101350; called by mutect2, varscan2
- RGS18 | c.476_478del p.E159del | In Frame Del (DEL) | VAF 18/130 reads (14%) | called by pindel, varscan2
- STEAP4 | c.930_950del p.I311_V317del | In Frame Del (DEL) | VAF 25/145 reads (17%) | called by mutect2, pindel
- USP34 | c.9918del p.K3306Nfs*3 | Frame Shift Del (DEL) | VAF 29/188 reads (15%) | called by mutect2, pindel, varscan2
- ACAA1 | c.309C>T p.I103= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs761918837, COSV57170703; called by muse, mutect2, varscan2
- B3GALT1 | c.126A>G p.T42= | Silent (SNP) | VAF 113/275 reads (41%) | catalogued as rs974228750, COSV59908113; called by muse, mutect2, varscan2
- CBLB | c.2484A>C p.A828= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV51421900; called by muse, mutect2, varscan2
- CDH26 | c.1335C>T p.S445= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as rs773935366, COSV54843160; called by muse, mutect2, varscan2
- DOCK2 | c.3429C>G p.G1143= | Silent (SNP) | VAF 35/355 reads (10%) | catalogued as COSV99915060; called by muse, mutect2
- GPRC6A | c.1467T>A p.T489= | Silent (SNP) | VAF 110/613 reads (18%) | catalogued as COSV59951697; called by muse, mutect2, varscan2
- GTF3C4 | c.825C>T p.L275= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs750309211, COSV100936079; called by muse, mutect2, varscan2
- LYST | c.8448G>A p.L2816= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as COSV101090221, COSV67703678; called by muse, mutect2, varscan2
- MTPAP | c.468G>A p.Q156= | Silent (SNP) | VAF 42/366 reads (11%) | catalogued as COSV53931537; called by muse, mutect2, varscan2
- MTRR | c.1110G>A p.L370= (on ENST00000264668; = p.L343= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/212 reads (10%) | catalogued as rs1237438820, COSV52945380, COSV99242067; called by muse, mutect2
- NR4A2 | c.432C>T p.D144= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59892705; called by muse, mutect2, varscan2
- PLA2G2A | c.69G>A p.V23= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100908638; called by muse, mutect2
- PLEKHG3 | c.3261G>A p.R1087= (on ENST00000394691; = p.R1143= on NM_001308147.2) | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV99907058; called by muse, mutect2
- PPARG | c.1095T>C p.D365= (on ENST00000287820 / NM_015869.5; = p.D335= on NM_005037.7) | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV55141138; called by muse, mutect2, varscan2
